HCMI case HCM-EXPT-1218-C18 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/f36d1708-d159-4429-a667-57107751c9ca

Demographics
Sex at birth: male; Days to birth: -24,654 days (67.5 years before the index date).

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.0; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Cecum; Classification of tumor: primary; Tumor grade: G2; Metastasis at diagnosis: No Metastasis; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Uicc clinical stage: Stage IIIA; Uicc pathologic m: M0; Uicc pathologic n: N0; Uicc pathologic stage: Stage IIA; Uicc pathologic t: T3; Uicc staging system edition: 7th.
   Pathology details: Lymphatic invasion present: No; Perineural invasion present: No; Vascular invasion present: No.
   Recorded as not given: neoadjuvant treatment (type not reported).

Molecular and laboratory tests
- MLH1 (IHC): Positive.
- MSH2 (IHC): Positive.
- MSH6 (IHC): Positive.
- PMS2 (IHC): Positive.
- Test: Negative; Mismatch repair mutation: Yes.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Colon Polyps; Days to comorbidity: 0 days; Days to risk factor: 0 days; Risk factors: Colon Polyps.

Exposures
- Tobacco smoking status: Current Smoker.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (1 sample)
- Sample HCM-EXPT-1218-C18-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
